Somatic mutation profile of tumor specimen TCGA-DM-A288-01A (aliquot TCGA-DM-A288-01A-11D-A16V-10) from TCGA case TCGA-DM-A288, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.7 years (25,084 days).
Specimen TCGA-DM-A288-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb0bda7e-7786-4e21-a25d-265c1d76e748.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A288-10A (Blood Derived Normal), aliquot TCGA-DM-A288-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8b4614e-31d9-42ce-b815-29095844f188

The open-access MAF lists 80 somatic variants for this specimen: 57 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 45, Silent 23, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2804dup p.Y935* | Nonsense Mutation (INS) | VAF 20/71 reads (28%) | hotspot (GDC flag); catalogued as rs863225332, CI023287, CI991958, COSV57344655; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 98/132 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 62/164 reads (38%) | catalogued as rs121918624, CM013787, COSV100321806; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.990dup p.V331Rfs*31 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs863223754; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.398T>G p.M133R | Missense Mutation (SNP) | VAF 16/23 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.129); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- ADAMTS16 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs377507889; called by muse, mutect2, varscan2
- AKNA | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747534212, COSV99800954; called by muse, mutect2, varscan2
- BSX | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545317; called by muse, mutect2, varscan2
- CACNA1G | c.5002C>T p.R1668C | Missense Mutation (SNP) | VAF 118/215 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1369128414, COSV61730920; called by muse, mutect2, varscan2
- CEP162 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 207/498 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV100003316, COSV57618180; called by muse, mutect2, varscan2
- CLIP2 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs767479757, COSV56278194; called by muse, mutect2, varscan2
- COL1A2 | c.2350-1G>A p.X784_splice | Splice Site (SNP) | VAF 103/239 reads (43%) | catalogued as COSV51957069; called by muse, mutect2, varscan2
- COL5A2 | c.2831G>A p.R944H | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs761988412, COSV100880710; called by muse, mutect2, varscan2
- CUBN | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913409; called by muse, mutect2, varscan2
- CYP4F22 | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99513101; called by muse, mutect2, varscan2
- DBH | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV55041858, COSV99708118; called by muse, mutect2, varscan2
- DDX31 | c.1138A>T p.S380C | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV60139621; called by muse, mutect2, varscan2
- DEXI | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100081177; called by muse, mutect2, varscan2
- DNAH9 | c.7561G>T p.E2521* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV52347253; called by muse, mutect2, varscan2
- EFL1 | c.1890G>T p.M630I | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV99188306; called by muse, mutect2, varscan2
- ETNK1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/17 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV99860944; called by muse, mutect2, varscan2
- FNDC1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376877270; called by muse, mutect2, varscan2
- FRYL | c.6242G>A p.S2081N | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV99977934; called by muse, mutect2, varscan2
- GGT5 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs762582016, COSV54071734; called by muse, mutect2, varscan2
- GREB1 | c.2975C>T p.T992I | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV99303651; called by muse, mutect2, varscan2
- H2BC3 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV100778316; called by muse, mutect2, varscan2
- KCNJ16 | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52258161, COSV99388659; called by muse, mutect2, varscan2
- LCTL | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100427302; called by muse, mutect2, varscan2
- LRTOMT | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV99194445; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs375735836; called by muse, mutect2, varscan2
- MCAM | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99876924; called by muse, mutect2, varscan2
- MOS | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100322993; called by muse, mutect2, varscan2
- MTUS2 | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.479); catalogued as COSV101462347; called by muse, mutect2, varscan2
- MYO18B | c.4561C>T p.R1521C | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749209387, COSV100124946; called by muse, mutect2, varscan2
- NDST3 | c.37A>G p.R13G | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.211); catalogued as rs140478292; called by muse, mutect2, varscan2
- OPRL1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768146093, COSV61091559; called by muse, mutect2, varscan2
- PDGFA | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775727803, COSV100627376, COSV63280452; called by muse, mutect2, varscan2
- PIK3CA | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV55877982, COSV55886419, COSV56022812; called by muse, mutect2, varscan2
- POLR2F | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428703324, COSV101328971; called by muse, mutect2, varscan2
- PRXL2A | c.412-1G>A p.X138_splice | Splice Site (SNP) | VAF 23/85 reads (27%) | catalogued as COSV100939827; called by muse, mutect2, varscan2
- PSG7 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV101343323; called by muse, mutect2, varscan2
- PTPRC | c.1944T>G p.D648E | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100723083; called by muse, mutect2
- RFX7 | c.295C>G p.H99D (on ENST00000559447 / NM_001368074.1; = p.H196D on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV57965479; called by muse, mutect2, varscan2
- SERPINA12 | c.605T>G p.M202R | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100369794; called by muse, mutect2, varscan2
- SFSWAP | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.374); catalogued as rs1228742040, COSV99906347; called by muse, mutect2, varscan2
- SLC28A3 | c.2063C>G p.S688C | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV100883326, COSV100883346; called by muse, mutect2, varscan2
- SNX29 | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs781245776, COSV100029974; called by muse, mutect2, varscan2
- TAB2 | c.1472T>G p.L491R | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99645068; called by muse, mutect2, varscan2
- TNN | c.1637C>G p.T546S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as COSV99512830; called by muse, mutect2, varscan2
- TSC22D1 | c.3146del p.P1049Lfs*38 (on ENST00000458659 / NM_183422.4; = p.P120Lfs*38 on NM_006022.4) | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs762485832; called by mutect2, pindel
- TUBA4A | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as rs769120095, COSV99944635; called by muse, mutect2, varscan2
- UBE3B | c.907A>C p.S303R | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV99784407; called by muse, mutect2, varscan2
- ZNF431 | c.1034A>T p.K345I | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100219012; called by muse, mutect2, varscan2
- APC | c.4381_4382del p.E1461Kfs*7 | Frame Shift Del (DEL) | VAF 60/122 reads (49%) | called by pindel, varscan2
- EHD3 | c.607del p.V203Sfs*16 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1161T>A p.D387E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.011); called by muse, mutect2
- SHOC1 | c.2674dup p.S892Ffs*9 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel
- AHNAK2 | c.3024C>T p.F1008= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs199609530, COSV60918735; called by muse, mutect2, varscan2
- ARFGAP1 | c.462G>A p.Q154= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV62263371; called by muse, mutect2, varscan2
- ASTN1 | c.147C>T p.R49= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV99922834; called by muse, mutect2, varscan2
- ATRNL1 | c.300A>G p.T100= | Silent (SNP) | VAF 52/196 reads (27%) | catalogued as COSV100746809; called by muse, mutect2, varscan2
- BASP1 | c.255G>A p.A85= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs1044009433, COSV100493863; called by muse, mutect2, varscan2
- CARF | c.1167G>A p.L389= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV57548247; called by muse, mutect2, varscan2
- CFLAR | c.177C>G p.L59= | Silent (SNP) | VAF 93/221 reads (42%) | catalogued as COSV100009828; called by muse, mutect2, varscan2
- ERN1 | c.396C>T p.T132= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs374999844; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT3 | c.7254C>A p.A2418= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV53130681; called by muse, mutect2, varscan2
- FFAR2 | c.705C>T p.F235= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as rs1286495129, COSV99876161; called by muse, mutect2, varscan2
- GDF6 | c.270G>A p.P90= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs776936551, COSV54625828; called by muse, mutect2, varscan2
- H4C4 | c.252C>T p.A84= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as rs772596789, COSV100534493; called by muse, mutect2, varscan2
- IGHM | c.849C>T p.S283= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs782635107; called by muse, mutect2, varscan2
- KRTAP15-1 | c.198T>G p.T66= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV61878158; called by muse, mutect2, varscan2
- MYLK | c.249C>T p.C83= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as rs149179973; called by muse, mutect2, varscan2
- RSPO4 | c.513C>T p.G171= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs753613363, COSV54081077; called by muse, varscan2
- SP4 | c.2310G>T p.S770= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs200932303, COSV99754965; called by muse, mutect2, varscan2
- TAL2 | c.60C>T p.S20= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs762534217, COSV61883890; called by muse, mutect2, varscan2
- TLR4 | c.2331C>A p.T777= (on ENST00000355622 / NM_138554.5; = p.T737= on NM_003266.4) | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100842842, COSV62923583; called by muse, mutect2, varscan2
- TTN | c.61125C>T p.S20375= (on ENST00000591111; = p.S12951= on NM_003319.4) | Silent (SNP) | VAF 19/207 reads (9%) | catalogued as rs997612485, COSV60389123; ClinVar: likely benign; called by muse, mutect2, varscan2
- TWF2 | c.417G>A p.S139= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs377702415; called by muse, mutect2, varscan2
- VAX2 | c.801G>A p.S267= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as rs782033743, COSV52265159; called by muse, mutect2, varscan2
- ZNF773 | c.102C>T p.D34= | Silent (SNP) | VAF 63/117 reads (54%) | catalogued as rs770582143, COSV56588451; called by muse, mutect2, varscan2
